Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8536, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8536-01A (Primary Tumor).

[page 1 of 6]
HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain, black & tarry stool.

Symptoms: Weakness; Weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies	
	Date of Last Menses	# of Live Births	
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____	

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status ☐ YES ☒ NO	TYPE	Packs/day	Duration (yrs)	When Quit (yr)
Alcohol Consumption				
Current Status ☒ YES ☐ NO	TYPE	Drinks/day	Duration (yrs)	When Quit (yr)
Drug Use				
Current Status ☐ YES ☒ NO	TYPE	Frequency	Duration (yrs)	When Quit (yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____	CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____	CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____	CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____	PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____	Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:					

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found at the pylorus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Stomach Cancer	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T3 N0 M0	Stage: II

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Extended Gastrectomy		
Primary Tumor		
Organ	Detailed Location	Size
Stomach Tumor	lesser curvature	2.5 x 2 x cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T3 N0 M0 Stage: II		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	2.5 x 2 x cm	lesser curvature	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₀ M ₀ Stage: II			
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution					Structural Pattern						
	+	-						+	-		
Diffuse					Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: Well ☒ Moderate ☐ Poor ☐

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				

Nuclear Grade: ☐ 0 ☒ I ☐ II ☐ III

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Adenocarcinoma of the stomach
(moderate ly differentiated) Grade: 2

Comments:

[page 6 of 6]
CELL DISTRIBUTION	+	-	STRUCTURAL PATTERN	+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis	X		Fibrosis		
Lymphocytic Infiltration		X	Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		
Otherwise Specified: D1 70%, D2 65%, D3 60%, D4 50% 10%											

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism				X
Nucleolar Prominent				X
Multinucleated Giant Cell				X
Mitotic Activity				X
Nuclear Grade				X

Histological Diagnosis: Adenocarcinoma NOS, G3

Source: NCI Genomic Data Commons file b29d8551-c85e-43bd-8abe-239c49bcb246 (TCGA-CD-8536.864BE0E2-A951-4E32-AF5F-A74A6B413642.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).